Somatic mutation profile of tumor specimen BA2824D (aliquot aq-BA2824D) from BEATAML1.0 case 2284, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 46.3 years (16,918 days).
Specimen BA2824D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c75d2d4-7780-40cf-be64-32c3c1ee5e60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2522D (Solid Tissue Normal), aliquot aq-BA2522D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5487a1dc-5b3e-49df-aca6-1b586771177a

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 2, Splice Region 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 23/80 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 12/41 reads (29%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, varscan2
- ATG2A | c.1102A>G p.M368V | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as rs1364368471; called by muse, mutect2, varscan2
- RSL1D1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.035); catalogued as rs1204114216; called by muse, mutect2, varscan2
- TRPV2 | c.333A>G p.T111= | Splice Region (SNP) | VAF 13/32 reads (41%) | catalogued as rs1433080811; called by muse, mutect2, varscan2
- XIRP2 | c.1135C>T p.Q379* (on ENST00000628543; = p.Q554* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 57/131 reads (44%) | catalogued as rs535459432, COSV99749030; called by muse, mutect2, varscan2
- BARHL1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- CSMD2 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- GPATCH4 | c.1101G>T p.Q367H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2
- USP2 | c.-42+7G>T | Splice Region (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
- ENPP7 | c.615C>T p.Y205= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs138491235; called by muse, mutect2, varscan2
- MED13L | c.5169T>C p.I1723= | Silent (SNP) | VAF 29/103 reads (28%) | called by muse, mutect2, varscan2
- OR2AP1 | c.108C>T p.S36= | Silent (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- ATF7IP | c.3280+450G>A | Intron (SNP) | VAF 24/60 reads (40%) | catalogued as rs942579863; called by muse, mutect2, varscan2
- MRE11 | c.20+82T>C | Intron (SNP) | VAF 33/79 reads (42%) | catalogued as rs772919522; called by muse, mutect2, varscan2
